Gene-level copy-number profile of tumor specimen TCGA-QQ-A5VC-01A from TCGA case TCGA-QQ-A5VC, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 63.9 years (23,357 days).
Specimen TCGA-QQ-A5VC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.4a64833d-52b2-4e4e-a7a7-500777415ac7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QQ-A5VC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/53196ae8-3766-43e8-85da-1520613584cb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 5,357; copy number 2: 26,076; copy number 3: 18,761; copy number 4: 6,412; copy number 5: 1,914; copy number 6: 669; copy number 7: 222; copy number 8: 12; copy number 9: 236; copy number 10: 111; copy number 11: 4; copy number 13: 25.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-QQ-A5VC-01A-31D-A32H-01): tumor purity 0.88, ploidy 2.5, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–2): AL359922.1.
- chr9:21,929,457–22,128,103, 8 genes (within-gene range 0–3): ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.
- chr18:39,622,123–39,665,494, 2 genes (within-gene range 0–2): MIR924, AC099845.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,193 genes in 36 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:102,763,322–102,853,842, 1 gene, copy number 5 (within-gene range 2–5): AC099567.1.
- chr1:150,730,188–152,196,699, 88 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:160,062,461–160,428,670, 20 genes, copy number 5: AL121987.1, KCNJ9, IGSF8, ATP1A2, ATP1A4, CASQ1, AL121987.2, PEA15, DCAF8, AL139011.2, AL139011.1, RPSAP18, PEX19, COPA, SUMO1P3, Y_RNA, NCSTN, NHLH1, RNU4-42P, VANGL2.
- chr1:199,752,491–199,909,648, 4 genes, copy number 8: AL596266.1, AL445687.1, RNU6-778P, AL445687.2.
- chr2:120,319,007–123,073,481, 30 genes, copy number 5: AC012363.2, INHBB, LINC01101, AC073257.2, AC073257.1, Y_RNA, AC018866.1, GLI2, AC017033.1, Y_RNA, AC067960.1, AC079988.1, TFCP2L1, RPS17P7, CLASP1, AC012447.1, RNU4ATAC, Y_RNA, NIFK-AS1, RPL12P15, AC018737.2, NPM1P32, NIFK, TSN, AC018737.1, LINC01823, AC011246.1, AC073632.1, AC062020.1, LINC01826.
- chr2:187,003,220–187,556,288, 1 gene, copy number 5 (within-gene range 3–5): AC007319.1.
- chr2:187,270,698–188,595,931, 10 genes, copy number 5: RNU6-989P, CALCRL, GAPDHP59, TFPI, LINC01090, ST13P2, AC104131.1, RNA5SP114, GULP1, MIR561.
- chr5:12,553,890–21,779,522, 125 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr5:45,890,216–50,846,519, 6 genes, copy number 5 (within-gene range 4–5): AC122694.1, EMB, AC112187.2, AC112187.1, AC112187.3, PARP8.
- chr6:41,335,608–53,924,125, 278 genes, copy number 6–13 (broad region; genes not listed).
- chr6:62,460,940–70,862,011, 68 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr6:122,211,648–170,738,536, 783 genes, copy number 5–7 (broad region; genes not listed).
- chr7:104,126,341–116,508,541, 148 genes, copy number 6–9 (within-gene range 4–9) (broad region; genes not listed).
- chr7:145,583,197–146,050,366, 3 genes, copy number 5: DPY19L4P2, AC006007.1, AC073308.1.
- chr7:146,208,665–146,311,822, 2 genes, copy number 5: AC073418.1, Y_RNA.
- chr8:4,633,065–4,788,584, 2 genes, copy number 5: AC022068.1, PAICSP4.
- chr8:71,197,433–88,019,113, 253 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr9:1,977,784–6,257,983, 79 genes, copy number 7–11 (broad region; genes not listed).
- chr9:22,446,824–23,438,700, 5 genes, copy number 5 (within-gene range 1–5): DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr9:131,852,928–132,079,867, 1 gene, copy number 5 (within-gene range 3–5): MED27.
- chr9:133,205,277–138,203,325, 217 genes, copy number 5 (broad region; genes not listed).
- chr11:49,852,096–49,884,421, 1 gene, copy number 5 (within-gene range 2–5): AP006587.6.
- chr11:49,871,826–57,038,436, 162 genes, copy number 5–9 (broad region; genes not listed).
- chr11:73,157,946–73,369,388, 8 genes, copy number 6 (within-gene range 3–6): AP002761.2, AP002761.1, P2RY2, AP002761.4, OR8R1P, P2RY6, AP002761.3, ARHGEF17.
- chr11:74,142,151–77,637,794, 110 genes, copy number 6–7 (broad region; genes not listed).
- chr11:78,533,176–79,441,030, 9 genes, copy number 6: AP003110.1, RNU6-311P, COPS8P3, TENM4, AP002768.1, AP002957.1, AP001547.1, MIR708, MIR5579.
- chr11:88,504,576–89,301,477, 6 genes, copy number 6 (within-gene range 3–6): GRM5, RNU6-16P, TYR, CBX3P7, AP000720.1, AP000720.2.
- chr14:25,431,193–29,500,460, 40 genes, copy number 5: AL079352.1, LINC02306, AL359396.1, AL359396.2, AL132633.1, CYB5AP5, NOVA1, AL079343.1, LINC02588, AL110292.1, LINC02294, LINC02293, AL132718.1, MIR4307HG, MIR4307, AL390334.1, LINC00645, MIR3171, BNIP3P1, AL139023.1, RPL26P3, LINC02300, EIF4A1P12, BTF3P2, FOXG1-AS1, AL049777.1, FOXG1, LINC01551, LINC02282, LINC02281, LINC02327, AL122126.1, LINC02326, Y_RNA, AL135878.1, RNU6-864P, AL133166.1, AL158058.1, AL158058.2, RNU11-5P.
- chr14:29,652,809–29,812,018, 2 genes, copy number 5: AL356756.1, RNU6-1234P.
- chr14:78,170,373–79,868,291, 1 gene, copy number 5 (within-gene range 4–5): NRXN3.
- chr14:78,695,321–87,332,390, 69 genes, copy number 5 (broad region; genes not listed).
- chr17:41,177,446–41,586,895, 40 genes, copy number 5: KRTAP4-2, KRTAP4-1, KRTAP4-17P, KRTAP9-1, KRTAP9-12P, KRTAP9-2, KRTAP9-3, KRTAP9-8, KRTAP9-4, KRTAP9-9, KRTAP9-6, KRTAP9-11P, KRTAP9-7, KRTAP9-10P, KRTAP29-1, KRTAP16-1, KRTAP17-1, TBC1D3P7, AC003958.1, KRT33A, KRT33B, KRT34, KRT31, AC003958.2, KRT41P, KRT37, KRT38, KRT43P, KRT32, RNU2-32P, KRT35, KRT36, KRT13, AC019349.1, KRT15, MIR6510, KRT19, LINC00974, KRT9, KRT14.
- chr17:46,721,582–52,160,017, 230 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr18:5,392,381–15,330,282, 262 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr21:10,328,411–17,450,104, 103 genes, copy number 5 (broad region; genes not listed).
- chr21:17,763,315–19,900,043, 26 genes, copy number 5–8: C21orf91-OT1, C21orf91, AL109761.1, CHODL-AS1, RPL37P3, CHODL, AF130417.1, TMPRSS15, AL109763.1, MIR548XHG, AF240627.1, MIR548X, PPIAP22, AL157359.3, AL157359.2, AL157359.1, AP000431.2, AP000431.1, SLC6A6P1, AP000855.1, RNU1-139P, RPL37P4, NIPA2P3, SREK1IP1P1, C1QBPP1, LINC01683.

Autosomal genes at a single copy (total copy number 1): 3,942. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
